Somatic mutation profile of tumor specimen 0DWI1B from CCDI case PBCNYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.4 years (4,161 days).
Specimen 0DWI1B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5fc0387-1a98-4b2f-a123-334c8f596a28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWHZ8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02b31221-70b7-4ed4-afa8-79a09339f482

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, 3'UTR 2, Intron 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 174/524 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 89/874 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 114/201 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD50 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 178/459 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.074); catalogued as rs1237901279; called by muse, mutect2, varscan2
- BUB1 | c.1355C>G p.T452R | Missense Mutation (SNP) | VAF 236/1084 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241421; called by muse, mutect2, varscan2
- CASR | c.1915C>T p.R639C (on ENST00000490131; = p.R716C on NM_000388.4) | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs768333005, COSV56135263; called by muse, mutect2, varscan2
- CNGA2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 124/552 reads (22%) | catalogued as rs141614710, COSV61705896; called by muse, mutect2, varscan2
- FBN3 | c.4688-1G>A p.X1563_splice | Splice Site (SNP) | VAF 94/505 reads (19%) | catalogued as rs763235992; called by muse, mutect2, varscan2
- GCKR | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 160/821 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53108340; called by muse, mutect2, varscan2
- ITGAD | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 60/740 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1206042214, COSV66759580; called by muse, mutect2
- MDN1 | c.12511G>A p.V4171I | Missense Mutation (SNP) | VAF 285/788 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs373882628; called by muse, mutect2, varscan2
- ROBO2 | c.2161G>A p.G721R | Missense Mutation (SNP) | VAF 107/674 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59927489; called by muse, mutect2, varscan2
- TUBA3C | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV67139512; called by muse, mutect2, varscan2
- ZNF493 | c.226C>G p.H76D | Missense Mutation (SNP) | VAF 151/588 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62749807; called by muse, mutect2, varscan2
- BAG4 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 114/494 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- KRTAP7-1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TEPSIN | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFRSF11A | c.1073A>C p.D358A | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GRIA1 | c.336C>T p.S112= | Silent (SNP) | VAF 147/491 reads (30%) | called by muse, mutect2, varscan2
- HTATSF1 | c.1965G>A p.G655= | Silent (SNP) | VAF 140/804 reads (17%) | called by muse, mutect2, varscan2
- ITPKB | c.2622C>T p.H874= | Silent (SNP) | VAF 65/316 reads (21%) | catalogued as rs144186587; called by muse, mutect2, varscan2
- PPHLN1 | c.423A>G p.P141= | Silent (SNP) | VAF 155/681 reads (23%) | called by muse, mutect2, varscan2
- KLK10 | c.*37C>T | 3'UTR (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- LY9 | c.*18G>T | 3'UTR (SNP) | VAF 70/389 reads (18%) | called by muse, mutect2, varscan2
- NLRC3 | c.2855+35G>T | Intron (SNP) | VAF 31/94 reads (33%) | called by muse, varscan2
- TRAF3IP3 | c.915+40G>A | Intron (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
